Somatic mutation profile of tumor specimen ALCH-B2U9-TTP1-A (aliquot ALCH-B2U9-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2U9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.8 years (20,739 days).
Specimen ALCH-B2U9-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1368a6d1-8f41-4a0d-87eb-4e1379c4a3f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2U9-NB1-A (Blood Derived Normal), aliquot ALCH-B2U9-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80b2a672-30b3-4bad-a3e7-673325b6ae6c

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, RNA 2, Splice Site 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 49/193 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs201202045; called by muse, mutect2, varscan2
- CPD | c.3351G>C p.E1117D | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as COSV56712861; called by muse, mutect2, varscan2
- KRT16 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.053); catalogued as rs1383463670, COSV56968949; called by muse, mutect2, varscan2
- SHISAL2B | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV101204042, COSV66620137; called by muse, mutect2
- TC2N | c.976A>G p.M326V | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs143905545; called by muse, mutect2
- THBS3 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.489); catalogued as rs1327807360; called by muse, mutect2, varscan2
- AGBL1 | c.3323+2T>G p.X1108_splice | Splice Site (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- ARAP2 | c.4660A>G p.T1554A | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ASXL3 | c.3813_3820delinsT p.T1272Ffs*6 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by pindel, varscan2*
- OXSR1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PPP4R3A | c.1405G>A p.E469K (on ENST00000554943 / NM_001366432.1; = p.E456K on NM_001284280.1) | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2
- PRR18 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, varscan2
- PTP4A2 | c.273A>T p.E91D | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC3A2 | c.646C>G p.Q216E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.232); called by muse, varscan2
- SLC5A1 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- TMBIM6 | c.696G>C p.K232N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP1 | c.1370G>A p.S457N | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF208 | c.1565A>T p.E522V | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AP2A2 | c.1911C>T p.D637= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs370327293; called by muse, mutect2, varscan2
- GPM6B | c.285G>A p.A95= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs759835302, COSV57423296; called by muse, mutect2, varscan2
- IL7 | c.258C>G p.R86= | Silent (SNP) | VAF 11/208 reads (5%) | called by muse, mutect2
- OR5AN1 | c.78A>G p.K26= | Silent (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- PPEF2 | c.1584C>T p.A528= | Silent (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- TRAF4 | c.895C>T p.L299= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- FBXL21P | n.1237G>A | RNA (SNP) | VAF 10/147 reads (7%) | catalogued as rs1381797603, COSV51809620; called by muse, mutect2
- MIR891A | n.19A>T | RNA (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- SEPTIN6 | c.-27G>A | 5'UTR (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
